Somatic mutation profile of tumor specimen TCGA-86-7714-01A (aliquot TCGA-86-7714-01A-12D-2167-08) from TCGA case TCGA-86-7714, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.9 years (22,619 days).
Specimen TCGA-86-7714-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d79c2668-6f1e-4736-ac9e-08e7fa58321d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-7714-10A (Blood Derived Normal), aliquot TCGA-86-7714-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1efa25a1-2998-4d61-a02c-f112e98322c4

The open-access MAF lists 90 somatic variants for this specimen: 65 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 23, In Frame Del 3, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.254T>A p.M85K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV51059828; called by mutect2, varscan2
- ABCB5 | c.2923G>T p.A975S (on ENST00000404938 / NM_001163941.2; = p.A530S on NM_178559.6) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV51723244; called by muse, mutect2, varscan2
- AHNAK2 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.742); catalogued as rs200025024, COSV60917709; called by muse, mutect2, varscan2
- AP5M1 | c.1313A>G p.D438G | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55107333; called by muse, mutect2, varscan2
- ARHGAP6 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375940153, COSV57298186, COSV57299143; called by muse, mutect2, varscan2
- ARHGEF15 | c.1448T>G p.V483G | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62726882; called by muse, mutect2, varscan2
- ARRDC5 | c.182G>A p.R61K (on ENST00000381781; = p.R47K on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV67788427; called by muse, mutect2
- ATP2B4 | c.3362C>G p.P1121R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV58178219, COSV58185423; called by muse, mutect2, varscan2
- ATP8B4 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as rs771488564, COSV52726608; called by muse, mutect2, varscan2
- BIRC6 | c.10403G>T p.R3468I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV70207688; called by muse, mutect2, varscan2
- CFHR2 | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66382464; called by muse, mutect2, varscan2
- CHCHD4 | c.389T>C p.I130T (on ENST00000396914 / NM_001098502.2; = p.I143T on NM_144636.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs751845757, COSV55500759; called by muse, varscan2
- CPSF7 | c.596A>T p.D199V (on ENST00000394888 / NM_001136040.4; = p.D242V on NM_024811.4) | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV61213299; called by muse, mutect2, varscan2
- CRX | c.553T>C p.S185P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55760394; called by muse, mutect2, varscan2
- DNASE2B | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as COSV65738150; called by muse, mutect2, varscan2
- DOCK4 | c.2927A>G p.N976S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.062); catalogued as COSV70244572; called by muse, mutect2
- DST | c.20003T>A p.L6668Q (on ENST00000361203 / NM_001374722.1; = p.L4365Q on NM_015548.5) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.991); catalogued as COSV55046902; called by muse, mutect2, varscan2
- DVL1 | c.1409A>T p.Y470F (on ENST00000378888 / NM_001330311.2; = p.Y445F on NM_004421.3) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV59566486; called by muse, mutect2, varscan2
- FOXRED2 | c.149A>T p.Q50L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV53401912; called by muse, mutect2, varscan2
- GPR85 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV51785805; called by muse, mutect2, varscan2
- GSE1 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53673650; called by muse, mutect2, varscan2
- IL22RA1 | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV54629157, COSV54630787; called by muse, mutect2, varscan2
- IL3RA | c.133A>G p.R45G | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58433864; called by muse, mutect2, varscan2
- KCNMA1 | c.2080G>T p.G694C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV54297587; called by muse, mutect2, varscan2
- KLHL1 | c.198C>A p.S66R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV64787261; called by muse, mutect2, varscan2
- LIG4 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV63598359; called by muse, mutect2, varscan2
- MAGEA4 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.936); catalogued as COSV52343507; called by muse, mutect2, varscan2
- MEMO1 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.227); catalogued as COSV54457876; called by muse, mutect2, varscan2
- MKKS | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV61399882, COSV61399973; called by muse, mutect2, varscan2
- MYH3 | c.2483G>T p.W828L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV56871120; called by muse, mutect2, varscan2
- NKX3-1 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373263457; called by muse, mutect2, varscan2
- NOTCH4 | c.5687A>T p.H1896L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as COSV66684643; called by muse, mutect2, varscan2
- OR14K1 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV99314924; called by muse, mutect2, varscan2
- OR5AS1 | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV57983730; called by muse, mutect2, varscan2
- PATJ | c.5296G>T p.A1766S | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as COSV64507462, COSV99054288; called by muse, mutect2, varscan2
- PBX1 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63349055; called by muse, mutect2, varscan2
- PCNX3 | c.4219A>T p.T1407S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV63141505; called by muse, mutect2, varscan2
- PHF7 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 22/113 reads (19%) | catalogued as COSV56233875, COSV56242215; called by muse, mutect2, varscan2
- PHKG1 | c.106C>G p.R36G | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52082032; called by muse, mutect2, varscan2
- PIK3C2B | c.2543C>T p.S848L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs368714819, COSV65814825; called by muse, mutect2, varscan2
- PRELP | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.175); catalogued as COSV58116444, COSV58117882; called by muse, mutect2, varscan2
- PTPN4 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs868582705, COSV55310632, COSV55310752; called by muse, mutect2, varscan2
- RIC1 | c.1522A>T p.I508F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV52616697, COSV99317886; called by muse, varscan2
- RP1L1 | c.1841G>T p.G614V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs768455479, COSV66757992, COSV66761441; called by muse, mutect2, varscan2
- SELL | c.493G>T p.A165S (on ENST00000650983; = p.A152S on NM_000655.5) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.201); catalogued as COSV99357336; called by muse, mutect2, varscan2
- SELL | c.492G>T p.K164N (on ENST00000650983; = p.K151N on NM_000655.5) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271269170, COSV99357338; called by muse, mutect2, varscan2
- SPRY4 | c.614G>A p.G205D (on ENST00000434127 / NM_001127496.3; = p.G228D on NM_030964.4) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59987018; called by muse, mutect2, varscan2
- TANC2 | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV67343103; called by muse, mutect2, varscan2
- TCTN3 | c.1406A>T p.Q469L | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV56452464; called by muse, mutect2, varscan2
- TENM4 | c.6412G>A p.V2138I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV53680239; called by muse, mutect2, varscan2
- TMEM215 | c.563A>C p.E188A | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.01); catalogued as COSV61364304; called by muse, mutect2, varscan2
- TRAK2 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs142579315; called by muse, mutect2
- YBX2 | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50302888; called by muse, mutect2, varscan2
- ZNF329 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV63773644; called by muse, mutect2, varscan2
- ZNF804A | c.1219G>T p.V407F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs568988606, COSV56476040; called by muse, varscan2
- ZNRF3 | c.2582C>T p.P861L (on ENST00000544604 / NM_001206998.2; = p.P761L on NM_032173.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs1400184077, COSV60439654; called by muse, mutect2
- CAPN2 | c.907_916del p.S303Lfs*2 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | called by mutect2, pindel, varscan2
- DIPK2A | c.295_303del p.P99_E101del | In Frame Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- GRIN2C | c.2211_2216del p.G738_K739del | In Frame Del (DEL) | VAF 36/102 reads (35%) | called by mutect2, pindel, varscan2
- PPP2R5B | c.1112del p.F371Sfs*17 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- PRKCZ | c.1368_1403del p.D456_Q468delinsE | In Frame Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel
- SETD2 | c.6393dup p.R2132Tfs*22 | Frame Shift Ins (INS) | VAF 25/107 reads (23%) | called by mutect2, pindel, varscan2
- SETD2 | c.2765del p.K922Sfs*8 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- AP3B2 | c.2556G>C p.L852= (on ENST00000261722; = p.L846= on NM_004644.5) | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV55615789; called by muse, mutect2
- CHD6 | c.5925C>T p.I1975= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as rs113638490, COSV64691715; called by muse, mutect2, varscan2
- CHRNG | c.939G>A p.L313= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV67316168; called by muse, mutect2, varscan2
- FADS3 | c.873C>T p.C291= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV53880969; called by muse, mutect2, varscan2
- LGI1 | c.498A>T p.T166= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV65059632; called by muse, mutect2, varscan2
- LGI4 | c.1161C>A p.P387= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV59535419; called by muse, mutect2, varscan2
- LRP2 | c.12924G>A p.T4308= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs753702869, COSV55579574; called by muse, mutect2, varscan2
- LTBP4 | c.1851C>T p.G617= (on ENST00000308370 / NM_001042544.1; = p.G580= on NM_003573.2) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV52592868; called by muse, mutect2
- OCA2 | c.2415C>T p.S805= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV62360347; called by muse, mutect2, varscan2
- OR2M5 | c.525C>A p.A175= | Silent (SNP) | VAF 65/287 reads (23%) | catalogued as COSV63547249; called by muse, mutect2, varscan2
- OR6K3 | c.453C>T p.I151= (on ENST00000368146; = p.I135= on NM_001005327.2) | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs1226236007, COSV63746743; called by muse, mutect2, varscan2
- PCDHGA5 | c.84C>T p.S28= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV53911857; called by muse, mutect2, varscan2
- PDZD8 | c.2604G>A p.Q868= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV53694201; called by muse, mutect2, varscan2
- PLCB1 | c.2541A>G p.T847= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV62072308; called by muse, mutect2, varscan2
- SLC17A7 | c.1464C>T p.V488= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV55550626; called by muse, mutect2, varscan2
- SLC24A4 | c.1080T>A p.G360= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV54123180; called by muse, mutect2, varscan2
- TENM3 | c.5136G>A p.L1712= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV101305329, COSV69322324; called by muse, mutect2
- TGIF2LX | c.636C>A p.A212= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV52215395, COSV52215472; called by muse, mutect2, varscan2
- TRRAP | c.1203C>G p.L401= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV62856609; called by muse, mutect2, varscan2
- UTS2 | c.66T>A p.P22= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV50014046; called by muse, mutect2, varscan2
- YLPM1 | c.2064G>T p.P688= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs749735666, COSV53121086, COSV53122794; called by muse, mutect2, varscan2
- ZNF670 | c.118C>T p.L40= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs1322758986, COSV63609258; called by muse, mutect2, varscan2
- ZNF91 | c.2301G>A p.E767= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV56087372, COSV56095380; called by muse, mutect2, varscan2
- SPATA20 | c.77+461G>A | Intron (SNP) | VAF 7/31 reads (23%) | catalogued as COSV50069449, COSV99135468; called by muse, mutect2, varscan2
- SSPOP | n.8887G>T | RNA (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100946937, COSV65139374; called by muse, varscan2
